Gene-level copy-number profile of tumor specimen C3N-01199-04 from CPTAC case C3N-01199, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Brain, NOS; Tumor grade: G2; Age at diagnosis: 48.9 years (17,847 days).
Specimen C3N-01199-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ec828501-db6f-43ab-940f-c8854618109d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01199-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/492407ae-bcfe-48b1-ae53-6d939b14e34f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 543; copy number 1: 84; copy number 2: 9,230; copy number 3: 2,009; copy number 4: 44,096; copy number 5: 12; copy number 6: 2,933.

Homozygous deletions (total copy number 0; autosomes only): 31 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:20,729,747–21,167,357, 31 genes: AC012414.4, RNU6-498P, AC012414.2, AC012414.3, LONRF2P3, AC012414.6, GRAMD4P5, AC012414.1, MIR3118-2, POTEB2, RNU6-749P, AC012414.5, AC037471.2, ZNF519P2, NF1P1, MIR5701-1, LINC01193, OR11J2P, OR11J5P, IGHD5OR15-5B, IGHD4OR15-4B, IGHD3OR15-3B, IGHD2OR15-2B, IGHD1OR15-1B, FAM30C, AC037471.1, BCAR1P2, RN7SL400P, AC126335.1, AC126335.2, BMS1P16.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 84. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
